Surgical pathology report (de-identified scan), TCGA case TCGA-ZG-A9L5, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University Medical Center Hamburg-Eppendorf, specimen TCGA-ZG-A9L5-01A (Primary Tumor).

[page 1 of 2]
Histopathological Report

Date of cancer sample procurement:

Date of pathology report:

Patient ID:

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
JW 1/23/14

Gross description:

1. (Prostate gland): Prostate gland: Weight: 76 g, Volume: 70 ml, Size: 5.7 x 4 x 4.5 cm. Adherent seminal vesicles and deferent duct: right side: 1 cm, left side: 1 cm. The surface is marked with green ink on the right side, blue ink on the left side. Total of the cross sections: 2.1 cm.
2. (Lymph nodes, right side): 7.5 x 5.5 x 3 cm measuring adipose tissue containing 1 nodes measuring up to 6.5 cm.
3. (Lymph nodes, left side): 3 x 3 x 1 cm measuring adipose tissue containing 1 nodes measuring up to 1.5 cm.

Microscopy:

1. Apex right and left: Right 8 tissue blocks, left 6 tissue blocks (total 14 tissue blocks). 4 cross sections: Right 24 tissue blocks, left 24 tissue blocks (total 48 tissue blocks). Basis right and left: Right 8 tissue blocks, left 9 tissue blocks (total 17 tissue blocks). Seminal vesicles right and left: Right 2 tissue blocks, left 2 tissue blocks (total 4 tissue blocks). Deferent ducts right and left: Right 1 tissue block, left 1 tissue block (total 2 tissue blocks).
2. Lymph nodes right: 24 tissue blocks.
3. Lymph nodes left: 4 tissue blocks.

Diagnosis:

1. (Prostate gland): Poorly differentiated prostatic adenocarcinoma, Gleason 5+4=9, (Gleason 5: 80%, Gleason 4: 15%). Tumor involves both lobes with the main focus in the prostate base. Maximum tumor diameter: 57 mm. Perineural invasion. Tumor infiltration into peri-prostatic adipose tissue in 11 tissue blocks with the main focus in the base and around the seminal vesicles on both sides (tissue blocks AR1A, L3B, L3D, L4C, BL1A, BL2A, BL3A, SBR1, SBR2, SBL1, SBL2; maximum invasion length 5 mm, maximal invasion depth 2 mm). Positive surgical margin in 23 blocks (AR1A, R1D, L2D, R3A, R4B, R4C, BR1A, BR1B, BR2A, BR2B, BR3A, BR3B, BR4B, BL2A, BL3B, BL4A, BL5, SBR1, SBL1, SBL3, DDR, DDL, maximum contact length 22 mm; Gleason 4-5). Negative peri-urethral resection margin.

Remaining prostatic tissue with small foci of prostatic intraepithelial neoplasia (high grade PIN) and signs of myoglandular hyperplasia of the prostate. Urothelium of the prostatic urethra without dysplasia. Tumor infiltration into both seminal vesicles and deferent ducts with positive resection margin.

[page 2 of 2]
2. (Lymph nodes, right side): One lymph node metastasis (6.5 cm) (1/1).
3. (Lymph nodes, left side): Two tumor-free lymph nodes (0/2).

Tumor classification

(in consideration of the intraoperative frozen-section, parallel report and immunohistochemical analyses):

pT4, Gleason 5+4=9 (Gleason 5: 80%, Gleason 4: 15%), maximum tumor diameter: 57 mm, tumor volume approx. 63 ml (Gleason 5: 50.4 ml, Gleason 4: 9.5 ml, Gleason 3: 3.1 ml), pN1 (1/3), R1

Comments:

The parallel transmittal revealed more adenocarcinoma infiltration in the sample "urinary bladder". Therefore the tumor has be staged as pT4.

In the preceding intraoperative frozen section the resection material of plexus and sphincter showed no adenocarcinoma.

One macroscopic image for tumor mapping.

Criteria:	W 1/4/14	Yes	No

Source: NCI Genomic Data Commons file 0590de4a-48ed-4b85-a329-a4209451bcb9 (TCGA-ZG-A9L5.FE097411-281D-4804-BAB4-D732A95EC689.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).